Gene-level copy-number profile of tumor specimen TCGA-BR-6458-01A from TCGA case TCGA-BR-6458, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 57.7 years (21,069 days).
Specimen TCGA-BR-6458-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.7c276b08-3aca-4862-af28-e937cf9a3bb8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-6458-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f854639-604f-4ee5-bcf6-eaa494139c8a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,698; copy number 2: 20,852; copy number 3: 25,591; copy number 4: 5,347; copy number 5: 3,698; copy number 6: 775; copy number 7: 481; copy number 8: 473; copy number 9: 113; copy number 11: 198; copy number 13: 128; copy number 16: 38; copy number 19: 94; copy number 21: 102; copy number 23: 21; copy number 33: 29; copy number 37: 125; copy number 42: 7; copy number 52: 33; copy number 58: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-6458-01A-11D-1799-01): tumor purity 0.45, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr16:78,495,926–78,553,296, 4 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,846 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,838,198–41,043,890, 88 genes, copy number 11 (broad region; genes not listed).
- chr1:41,098,638–41,099,136, 1 gene, copy number 11: RPL23AP17.
- chr1:112,177,234–118,989,556, 141 genes, copy number 7–13 (broad region; genes not listed).
- chr1:119,748,002–121,580,524, 48 genes, copy number 9: HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:164,555,584–165,941,769, 32 genes, copy number 7: PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1.
- chr1:168,400,829–169,630,193, 28 genes, copy number 7: AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP.
- chr1:169,690,665–169,764,705, 2 genes, copy number 7 (within-gene range 5–7): SELL, SELE.
- chr1:224,896,262–227,318,474, 55 genes, copy number 7 (within-gene range 4–7): DNAH14, LBR, LINC02765, AC092811.1, ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1, RPS3AP7, RN7SKP165, CDKN2AIPNLP1, AL359704.2, STUM, ITPKB, ITPKB-IT1, ITPKB-AS1, RPS27P5, AL359732.1, PSEN2, AL391628.1, COQ8A, AL353689.1, CDC42BPA, AL353689.2, AL353689.3, AL451047.1, AL627308.1, AL627308.2, AL627308.3.
- chr2:101,696,850–105,636,637, 68 genes, copy number 8 (broad region; genes not listed).
- chr2:116,687,218–121,285,202, 64 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr5:36,485,343–43,067,452, 113 genes, copy number 11–16 (broad region; genes not listed).
- chr5:43,874,367–45,895,970, 17 genes, copy number 9: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:10,207,670–17,680,659, 79 genes, copy number 7 (broad region; genes not listed).
- chr7:43,582,758–48,711,582, 112 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr7:55,019,017–57,837,046, 143 genes, copy number 7–58 (broad region; genes not listed).
- chr7:82,754,012–98,252,232, 206 genes, copy number 11–33 (broad region; genes not listed).
- chr8:7,414,855–7,952,413, 44 genes, copy number 19 (within-gene range 6–19): DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, AC134684.11, PRR23D1, AC134684.12, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC134684.10, AC084121.2, AC084121.3, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, AC084121.4, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A.
- chr8:8,665,497–18,401,218, 229 genes, copy number 19–52 (broad region; genes not listed).
- chr11:19,117,099–24,262,218, 60 genes, copy number 7–8: ZDHHC13, CSRP3, CSRP3-AS1, E2F8, PCNAP4, AC009652.1, NAV2, NAV2-IT1, RNA5SP335, NAV2-AS5, NAV2-AS4, MIR4486, AC023950.1, AC009549.1, MIR4694, NAV2-AS3, NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686.
- chr18:48,539,031–48,863,217, 1 gene, copy number 7 (within-gene range 3–7): CTIF.
- chr18:48,661,840–50,319,120, 50 genes, copy number 7: AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320, RN7SL310P, CFAP53, AC090246.1, MBD1, CXXC1, AC105227.1, AC105227.2, RNA5SP458.
- chr20:87,250–12,381,255, 265 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
